CCDI case PBBWLE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasal cavity and middle ear.
https://portal.gdc.cancer.gov/cases/ce8b9b14-9a15-48da-a083-f8210bad1533

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Middle ear; Age at diagnosis: 6.2 years (2,249 days).

Biospecimens (3 samples)
- Sample 0DJG6Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJG8P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJGE0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
